Gene-level copy-number profile of tumor specimen TCGA-CC-5263-01A from TCGA case TCGA-CC-5263, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 35.2 years (12,863 days).
Specimen TCGA-CC-5263-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.19f16a5f-d34a-4a13-990c-362a96105262.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-5263-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a036116-a0d9-4888-98c8-25e8eb267d0c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 11,928; copy number 2: 38,619; copy number 3: 9,108; copy number 4: 65; copy number 5: 11; copy number 6: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-5263-01A-01D-A12Y-01): tumor purity 0.77, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:110,007,675–111,699,033, 48 genes: AC013268.3, AC013268.2, AC013268.4, MIR4267, MALL, MIR4436B1, NPHP1, ACTR1AP1, MTLN, AC140479.3, AC140479.4, MALLP1, MIR4436B2, AC140479.5, AC140479.1, AC140479.2, LINC01106, ZBTB45P2, GPAA1P2, AC112229.4, AC112229.1, AC112229.3, LIMS4, AC112229.2, AC108938.1, RGPD6, AC226101.1, RPL22P12, BUB1, AC114776.1, ACOXL, RPL5P9, MIR4435-2HG, ACOXL-AS1, BCL2L11, AC108463.2, AC108463.1, AC108463.3, AC068491.1, AC068491.2, RPS14P4, MIR4435-2, PAFAH1B1P2, AC017002.3, AC017002.2, SOCAR, DBF4P2, AC017002.1.
- chr2:111,675,026–111,675,343, 1 gene: RPL34P8.
- chr10:87,396,561–87,863,533, 14 genes (within-gene range 0–2): FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr13:63,737,511–64,076,044, 10 genes: OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr16:72,665,123–72,822,781, 4 genes (within-gene range 0–1): AC004943.2, RNU7-90P, KRT18P18, AC004943.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,529,467–20,679,243, 7 genes, copy number 5: NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3.
- chr17:40,019,097–40,093,867, 4 genes, copy number 5 (within-gene range 3–5): MED24, MIR6884, SNORD124, THRA.
- chr18:74,073,353–74,390,297, 8 genes, copy number 6: FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1.

Autosomal genes at a single copy (total copy number 1): 9,548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
